Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A1L4, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A1L4-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: [REDACTED]
Account #: [REDACTED] Date of Procedure: [REDACTED]
DOB: [REDACTED] Date of Receipt: [REDACTED]
Physician: [REDACTED]
CC: [REDACTED]

....

Specimens Submitted:
1: SP: Retroperitoneal liposarcoma
2: SP: Retroperitoneal fat

ICD-0-3
Dedifferentiated liposarcoma 8858/3
Site: retroperitoneum C48.0
2/2/11
mu

DIAGNOSIS:

1. SOFT TISSUE, RETROPERITONEUM; RESECTION:
- DEDIFFERENTIATED LIPOSARCOMA INVOLVING SOFT TISSUE AND SKELETAL MUSCLE
- TUMOR SIZE: 19.5 x 15.0 x 8.5 CM
- DEDIFFERENTIATED COMPONENT SHOWS LOW GRADE MYXOFIBROSARCOMA-LIKE AREAS TO HIGH GRADE SPINDLE AND PLEOMORPHIC SARCOMA, (MALIGNANT FIBROUS HISTIOCYTOMA-INFLAMMATORY TYPE)
- WELL DIFFERENTIATED COMPONENT, LIPOMA-LIKE AND SCLEROSING TYPES, ARE PRESENT
- TUMOR IS SEEN WITHIN 1MM FROM SKELETAL MUSCLE. PORTION OF WELL-DIFFERENTIATED COMPONENT IS COVERED BY THIN CAPSULE.
- KIDNEY CAPSULE MARGIN SHOWS ATYPICAL CELLS (WITHIN 1MM OF INKED MARGIN) CONSISTENT WITH INVOLVEMENT BY WELL-DIFFERENTIATED LIPOSARCOMA
- NECROSIS IS PRESENT COMPRISING ABOUT 25% OF THE TOTAL TUMOR VOLUME (GROSS ESTIMATE).
2. ADIPOSE TISSUE, RETROPERITONEUM; EXCISION:
- ADIPOSE TISSUE WITH MICROSCOPIC FOCI OF ATYPICAL CELLS CONSISTENT WITH INVOLVEMENT BY WELL-DIFFERENTIATED LIPOSARCOMA.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:	Special Stain	Comment
Result	RECUT	

** Continued on next page **

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]
MRN: [REDACTED]
Account #: [REDACTED]

Accession #: [REDACTED]
Physician: [REDACTED]
Service: [REDACTED]

Page 2 of 3

RECUT

Gross Description:

1.) The specimen is fresh labeled "retroperitoneal liposarcoma" and consists of a multilobulated rubbery mass measuring 19.5 x 15.0 x 8.5 cm with a portion of fibroadipose tissue measuring 19.0 x 15.0 x 2.5 cm oriented with one stitch designating kidney capsule. The attached are portions of skeletal muscle. The sectioning reveals biphasic appearance of the tumor composed of tan firm lobulated components which is sharply demarcated from the soft lipomatous component present in approximately equal amount. The firm component shows area of necrosis which comprise approximately 25% of the total tumor volume. The tumor appears to be partially surrounded by distinct fibrous capsule in the area of soft tumor component while the firm component apparently infiltrates the adjacent skeletal muscle. Surgical margin is inked black. Designated the kidney capsule margin is remote. Gross photographs are taken. Representative sections are submitted.

Summary of sections:

KCM - kidney capsule margin
TM - tumor to margin
TS tumor, soft area
TF tumor, firm
TSF tumor, transition between soft and firm area

2.) The specimen is received fresh labeled "retroperitoneal" and consists of multiple pieces of fibroadipose tissue measuring 17 x 15 x 5.5 cm in aggregate. Sectioning is unremarkable. Representative sections are submitted. Additional sections are submitted.

Summary of sections:

U-undesignated

Summary of Sections:

Part 1: SP: Retroperitoneal liposarcoma

Block	Sect.	Site	PCs
1		KCM	3
5		TF	5
4		TM	4
5		TS	5
5		TSF	5

** Continued on next page **

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Patient:

MRN:

Account #:

Accession #:

Physician:

Service:

----- Page 3 of 3

Part 2: SP: Retroperitoneal fat

Block	Sect.	Site	PCs
10		U	10

**** End of Report ****

Source: NCI Genomic Data Commons file b235f2da-e4d0-43b3-9254-a0c057243474 (TCGA-DX-A1L4.F65044C7-8CC3-45D8-8910-4B9BCA7C88A7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).